CCDI case PBCDLV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e7ce3a8a-cf0a-41cc-b405-92691f9872b5

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 5.6 years (2,058 days).

Biospecimens (3 samples)
- Sample 0DPCXR: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPCXX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DPCY3: Tissue type: Tumor; Specimen type: Solid Tissue.
